Gene-level copy-number profile of tumor specimen TCGA-57-1993-01A from TCGA case TCGA-57-1993, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.1 years (20,498 days).
Specimen TCGA-57-1993-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.bb7d6126-2bf6-41ab-b657-da66ba7abd8c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-57-1993-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c445d43-2ecb-44b1-8e76-e6bda7a0fa54

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 585; copy number 2: 2,849; copy number 3: 17,978; copy number 4: 21,475; copy number 5: 12,109; copy number 6: 3,606; copy number 7: 385; copy number 8: 155; copy number 9: 54; copy number 10: 4; copy number 11: 183; copy number 12: 126; copy number 13: 30; copy number 14: 27; copy number 15: 7; copy number 16: 13; copy number 17: 8; copy number 18: 60; copy number 20: 22; copy number 21: 2; copy number 22: 11; copy number 23: 32; copy number 24: 40; copy number 25: 9; copy number 36: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-57-1993-01A-01D-0648-01): tumor purity 0.82, ploidy 4.12, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 667 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,421,979–33,032,469, 23 genes, copy number 23 (within-gene range 5–23): AL356986.1, LRRC37A12P, RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A, ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1.
- chr1:92,029,985–92,961,522, 26 genes, copy number 24 (within-gene range 4–24): EPHX4, LPCAT2BP, SETSIP, BTBD8, GAPDHP46, PRKAR1AP1, AC104836.1, AL663109.1, C1orf146, ACTBP12, GLMN, RPAP2, RN7SL824P, GFI1, EVI5, AL354890.1, HMGB3P9, RNU4-59P, AC104332.1, H3P3, CCNJP2, RPL5, DIPK1A, SNORD21, SNORA66, AL162740.1.
- chr1:98,890,245–99,005,032, 1 gene, copy number 21: PLPPR5.
- chr1:99,008,218–99,008,474, 1 gene, copy number 21: AL445433.1.
- chr6:33,572,547–33,696,574, 3 genes, copy number 10 (within-gene range 8–10): BAK1, LINC00336, ITPR3.
- chr6:33,698,128–33,698,234, 1 gene, copy number 10: MIR3934.
- chr11:32,112,049–32,343,409, 1 gene, copy number 14 (within-gene range 3–14): THEM7P.
- chr11:32,387,775–33,674,102, 29 genes, copy number 9–14 (within-gene range 7–14): WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4, EIF3M, HNRNPA3P9, CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, AL136126.1, HIPK3, KIAA1549L, AL137161.1, AL133399.1.
- chr12:9,448,295–12,211,084, 103 genes, copy number 13–24 (within-gene range 5–24) (broad region; genes not listed).
- chr12:12,155,262–12,155,772, 1 gene, copy number 24: AC007537.1.
- chr12:24,566,964–27,972,733, 86 genes, copy number 9–36 (broad region; genes not listed).
- chr17:1,344,275–1,562,792, 8 genes, copy number 17: YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA.
- chr19:11,131,520–14,031,557, 183 genes, copy number 11 (broad region; genes not listed).
- chr19:23,817,599–24,129,968, 13 genes, copy number 16 (within-gene range 6–16): AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40.
- chr19:28,435,388–31,787,255, 62 genes, copy number 9–25 (within-gene range 6–25) (broad region; genes not listed).
- chr19:35,799,988–38,587,564, 126 genes, copy number 12 (within-gene range 6–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 585. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
